Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6815, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6815-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 1

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age: Gender: F

Material: **Total organ resection – stomach**

Unit in charge:

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: **Gastric cancer**

Examination performed on:

Macroscopic description:

The tested material consisting of the stomach, having been cut out along the greater curvature sized 18 x 13 cm with the omentum sized 23 x 7 x 2 cm. Tumour sized 5.3 x 3.9 x 1.8 cm found on the front wall. Distance from the proximal boundary: 5.4 cm, from distal boundary: 9.2 cm.

Microscopic description:

Adenocarcinoma tubulare necroticans venticuli (G2, intestinal type) - in tilt ratio parietis totae ventriculi.

The incision lines and omentum free neoplastic lesions. Nodes of lesser curvature: metastases in lymphonodis (II/X).

Nodes of greater curvature: metastases in lymphonodis (III/IX).

Histopathological diagnosis:

Adenocarcinoma tubulare venticuli. Tubular adenocarcinoma of the stomach. Metastases in lymphonodis. Cancer Metastases in lymph nodes (V/XIX). (G2, pT2, pN2).

CONTACT YOUR DOCTOR WITH THIS REPORT!

Compliance validated by:

Source: NCI Genomic Data Commons file ad14b049-4c0a-4a9a-97a2-89b692c51c20 (TCGA-D7-6815.68B9ED97-DF0D-4AD2-8D9D-48A1D643B500.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).